Gene-level copy-number profile of tumor specimen TCGA-33-4586-01A from TCGA case TCGA-33-4586, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 57.9 years (21,148 days).
Specimen TCGA-33-4586-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.d79fd16c-cd7f-4ecf-8224-115df9ce64ed.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-33-4586-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b99ef27b-687b-4dbc-b4e6-51d3cc4674fe

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 62; copy number 1: 413; copy number 2: 22,720; copy number 3: 12,083; copy number 4: 12,955; copy number 5: 3,669; copy number 6: 7,150; copy number 8: 192; copy number 9: 146; copy number 10: 194; copy number 11: 175; copy number 12: 27; copy number 16: 3; copy number 21: 3; copy number 23: 8; copy number 30: 6; copy number 33: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-33-4586-01A-01D-1439-01): tumor purity 0.42, ploidy 3.27, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 62 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,201,469–22,214,672, 44 genes: IFNA7, IFNA10, IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14, IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.
- chr11:9,754,770–10,611,689, 18 genes (within-gene range 0–2): LINC02709, SBF2-AS1, SBF2, AC011092.2, RNU7-28P, AC011092.1, AC011092.3, AC100763.1, AC080023.2, AC080023.1, ADM, AMPD3, RNU6ATAC33P, MTRNR2L8, MIR4485, RNF141, IRAG1-AS1, LYVE1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 11,581 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–248,919,946, 2,604 genes, copy number 6 (broad region; genes not listed).
- chr3:83,924,157–113,629,575, 322 genes, copy number 6–33 (within-gene range 4–33) (broad region; genes not listed).
- chr3:113,964,137–114,056,594, 1 gene, copy number 6 (within-gene range 4–6): CCDC191.
- chr3:113,998,782–198,222,513, 1,515 genes, copy number 6–11 (within-gene range 4–11) (broad region; genes not listed).
- chr5:8,980,404–45,895,970, 526 genes, copy number 5–6 (broad region; genes not listed).
- chr7:102,813,230–112,896,625, 137 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr7:113,075,124–159,233,377, 937 genes, copy number 6 (broad region; genes not listed).
- chr11:94,962,620–95,748,715, 19 genes, copy number 5 (within-gene range 3–5): CWC15, KDM4D, AP002383.1, KDM4E, AP002383.5, AP002383.3, AP002383.4, KDM4F, AP001264.1, SRSF8, ENDOD1, BUD13P1, AP000787.2, AP000787.1, SESN3, AP000787.3, AP001790.1, AP000820.2, AP000820.1.
- chr12:66,767–72,670,758, 1,819 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr13:62,321,305–62,574,905, 6 genes, copy number 5: LINC01074, LINC00459, RPL32P28, AL356102.1, SQSTM1P1, AL445668.1.
- chr14:18,333,726–29,372,406, 514 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr14:34,709,113–36,679,362, 59 genes, copy number 5: CFL2, RPL12P6, BAZ1A, RNU7-41P, AL121603.2, SRP54-AS1, AL121603.1, IGBP1P1, SRP54, FAM177A1, PPP2R3C, AL049776.1, PRORP, AL121594.1, RPL23AP70, SEPTIN7P1, MRPL57P8, DPRXP3, RPL7AP3, RPL9P3, PSMA6, AL133163.2, AL133163.1, NFKBIA, DNAJC8P1, AL133163.3, RPS3AP4, KRT18P6, INSM2, RALGAPA1, AL137818.1, QRSL1P3, AL162311.3, NUTF2P2, BRMS1L, AL162311.1, AL162311.2, AL133304.3, AL133304.1, ILF2P2, AL133304.2, LINC00609, PTCSC3, AL162511.1, RN7SKP21, MBIP, AL132857.1, DPPA3P2, RNU7-93P, SFTA3, SFTA3, NKX2-1, NKX2-1-AS1, PHKBP2, RPL29P3, NKX2-8, RN7SKP257, AL079303.1, PAX9.
- chr14:36,788,644–36,828,729, 2 genes, copy number 5: AL162464.2, AL162464.1.
- chr14:37,595,847–41,904,549, 44 genes, copy number 5 (within-gene range 2–5): TTC6, AL136296.1, RNU6-1277P, LINC00517, AL359233.1, AL392023.2, AL392023.1, SSTR1, CLEC14A, AL355835.1, AL357094.1, KRT8P1, LINC00639, AL132994.1, AL132994.2, Y_RNA, SEC23A, AL109628.1, SEC23A-AS1, PPIAP4, GEMIN2, TRAPPC6B, AL109628.2, RPL7AP2, AL132639.3, PNN, AL132639.1, YTHDF2P1, MIA2, AL132639.2, GLRX5P3, COILP1, FBXO33, AL049828.1, AL049828.2, AL390800.1, LINC02315, AL391516.1, AL356596.1, AL121821.3, AL121821.2, AL121821.1, LRFN5, FKBP1BP1.
- chr16:18,317,942–35,912,516, 741 genes, copy number 5 (broad region; genes not listed).
- chr19:7,112,255–40,414,793, 1,390 genes, copy number 6–9 (within-gene range 2–9) (broad region; genes not listed).
- chr19:43,951,223–44,448,578, 29 genes, copy number 8–10: ZNF221, ZNF155, AC006213.4, AC006213.5, AC006213.1, ZNF230, AC067968.2, ZNF222, AC067968.1, ZNF223, ZNF284, RNU6-902P, ZNF224, AC021092.1, ZNF225, ZNF234, AC138470.2, ZNF226, ZNF227, ZNF235, AC138470.1, ZNF233, AC138473.1, NDUFA3P1, ZNF112, AC245748.1, ZNF285, AC245748.2, ZNF229.
- chr19:50,136,859–58,605,223, 651 genes, copy number 6 (broad region; genes not listed).
- chr20:19,000,709–32,608,893, 265 genes, copy number 5–6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 337. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
